Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A8GK, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A8GK-06A (Metastatic).

ICD O.3

Melanoma NOS 8720/3

Site @ Buttock, soft tissue 049.5

11/27/13

DIAGNOSIS

(A) LEFT BUTTOCK MASS:
METASTATIC MALIGNANT MELANOMA, MARGINS FREE.

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) EXCISION LEFT BUTTOCK MASS WITH GLUTEUS MUSCLE, SHORT STITCH PROXIMAL, LONG STITCH LEFT LATERAL - An ellipse of tan skin (7.0 x 3.0 excised to a depth of 3.0 cm) with underlying subcutaneous tissue and skeletal muscle along its deep aspect. The specimen is marked with a short stitch denoting proximal and a long stitch denoting lateral.

Cut section reveals a fairly well circumscribed dusky gray-black tumor (1.8 x 1.7 x 1.5 cm) that is 1.1 cm from the nearest deep margin, 1.0 cm from the nearest proximal margin, and 0.7 cm from the nearest distal margin. Adjacent to the tumor is an area of fibrosis (2.0 x 2.0 x 0.5 cm).

The overlying skin is unremarkable. Representative portions of tumor and normal are submitted for tumor bank.

INK CODE: Blue = proximal, orange = distal, black = deep.

SECTION CODE: A1, tumor with deep margin; A2, tumor with distal margin; A3, tumor with proximal margin; A4, skin, representative; A5, tumor and adjacent fibrous tissue.

CLINICAL HISTORY

None given.

SNOMED CODES

T-D2600, M-87206

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Released by:

-----END OF REPORT-----

HPV Discrepancy		☒

Source: NCI Genomic Data Commons file c5bed4a5-294c-4735-a042-28f63975dde6 (TCGA-D3-A8GK.42B80510-CCC7-4934-9D6B-6D0097B7F061.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).